Somatic mutation profile of tumor specimen TCGA-55-7570-01A (aliquot TCGA-55-7570-01A-11D-2036-08) from TCGA case TCGA-55-7570, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 60.8 years (22,218 days).
Specimen TCGA-55-7570-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 231d8ad3-1bf2-4171-aed4-863667c7a41f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7570-10A (Blood Derived Normal), aliquot TCGA-55-7570-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80033295-4cbb-4276-80a1-0cdebf93fbd6

The open-access MAF lists 410 somatic variants for this specimen: 319 protein-altering or splice-affecting, 80 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 80, Nonsense Mutation 19, Frame Shift Del 11, Splice Site 5, Intron 5, Frame Shift Ins 4, Splice Region 3, 5'Flank 2, 3'UTR 2, In Frame Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.488A>G p.Y163C | Missense Mutation (SNP) | VAF 38/64 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148924904, CM942135, COSV52663142, COSV52676381; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.4125C>A p.F1375L | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748390950, COSV55292984, COSV55300076; called by muse, mutect2, varscan2
- ABCC12 | c.2312C>A p.S771Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs1446720631, COSV60914321; called by muse, mutect2, varscan2
- AC127029.3 | c.394G>C p.A132P | Missense Mutation (SNP) | VAF 114/206 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM099827, COSV60110191, COSV60111291; called by muse, mutect2, varscan2
- ACAD9 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV58308146; called by muse, mutect2, varscan2
- ADAM18 | c.910-1G>T p.X304_splice | Splice Site (SNP) | VAF 39/69 reads (57%) | catalogued as COSV55849539; called by muse, mutect2, varscan2
- ADAMTS5 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.806); catalogued as COSV53180415; called by muse, mutect2, varscan2
- ADAMTSL1 | c.785A>C p.K262T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV52818205; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2738G>T p.R913L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54454460, COSV54460328; called by muse, mutect2, varscan2
- ALCAM | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV60250434; called by muse, mutect2, varscan2
- ALOX5 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as rs1461945517, COSV65552995; called by muse, mutect2, varscan2
- ALX1 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); catalogued as COSV57492843; called by muse, mutect2, varscan2
- ALX1 | c.269C>G p.T90S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.341); catalogued as COSV57492853; called by muse, mutect2, varscan2
- ANK2 | c.1558A>T p.M520L | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.673); catalogued as COSV52169230; called by muse, mutect2, varscan2
- ANKFN1 | c.1959G>C p.W653C | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59451139; called by muse, mutect2, varscan2
- ANKRD30A | c.1646A>G p.D549G (on ENST00000611781; = p.D493G on NM_052997.2) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV64613454; called by muse, mutect2, varscan2
- ANO5 | c.1254A>T p.E418D | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV61086526; called by muse, mutect2, varscan2
- AOC3 | c.1334C>G p.S445* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV53825661, COSV53827494; called by muse, mutect2, varscan2
- AOPEP | c.834C>G p.N278K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52919542; called by muse, mutect2, varscan2
- ARAP2 | c.4038G>C p.R1346= | Splice Region (SNP) | VAF 9/31 reads (29%) | catalogued as COSV58288415; called by muse, mutect2, varscan2
- ARHGEF17 | c.1220G>T p.S407I | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.06); catalogued as rs776838575, COSV55234005; called by muse, mutect2, varscan2
- ARID4B | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV51605808; called by muse, mutect2, varscan2
- ASTN1 | c.2377+1G>T p.X793_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV56063323; called by muse, mutect2, varscan2
- ATP10A | c.3746A>G p.N1249S | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.109); catalogued as COSV63519245; called by muse, mutect2, varscan2
- ATRNL1 | c.3121C>G p.Q1041E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1554936026, COSV58094656; called by muse, mutect2, varscan2
- BOLL | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.442); catalogued as COSV56575054; called by mutect2, varscan2
- BRCA1 | c.1254G>C p.E418D | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.58); catalogued as COSV58793008; called by muse, mutect2, varscan2
- BRIP1 | c.2082C>G p.F694L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52001820; called by muse, mutect2, varscan2
- BTN2A2 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV61857796; called by muse, mutect2, varscan2
- C20orf194 | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 14/57 reads (25%) | catalogued as COSV52697774; called by muse, mutect2, varscan2
- C2orf80 | c.325A>G p.I109V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV58017421; called by muse, mutect2, varscan2
- C4orf46 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.323); catalogued as COSV57015373; called by muse, mutect2
- CACNA1E | c.64A>T p.S22C | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.338); catalogued as COSV62401874; called by muse, mutect2, varscan2
- CAMTA1 | c.1113C>A p.D371E | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.301); catalogued as rs377684384, COSV57908146; called by muse, mutect2, varscan2
- CAPN5 | c.1409A>G p.K470R (on ENST00000456580; = p.K430R on NM_004055.5) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV53689103; called by muse, mutect2, varscan2
- CCDC85A | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV68152452; called by muse, mutect2, varscan2
- CCP110 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV66817211; called by muse, mutect2, varscan2
- CD163 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63134026; called by muse, mutect2, varscan2
- CDH23 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as CM088225, COSV54939875; called by muse, mutect2, varscan2
- CEACAM19 | c.481G>T p.A161S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as COSV62552093; called by muse, mutect2, varscan2
- CEND1 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.919); catalogued as COSV57193899; called by muse, mutect2, varscan2
- CEP152 | c.4552G>T p.G1518* (on ENST00000380950 / NM_001194998.2; = p.G1462* on NM_014985.4) | Nonsense Mutation (SNP) | VAF 15/70 reads (21%) | catalogued as COSV57860811; called by muse, mutect2, varscan2
- CEP41 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.079); catalogued as COSV56219513; called by muse, mutect2, varscan2
- CFAP43 | c.4066G>T p.D1356Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63853540; called by muse, mutect2, varscan2
- CFAP54 | c.6658G>C p.V2220L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV61572892, COSV61576205; called by muse, mutect2, varscan2
- CFH | c.3634C>T p.H1212Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV66410045, COSV66414787; called by muse, mutect2, varscan2
- CFHR1 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757982174, COSV57627758; called by muse, varscan2
- CFHR2 | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774655640, COSV66381395; called by muse, mutect2, varscan2
- CHAT | c.1433C>G p.P478R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100341027, COSV60327335; called by muse, mutect2, varscan2
- CHD1 | c.3427G>T p.G1143C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV52341829; called by muse, mutect2, varscan2
- CHRDL1 | c.169G>T p.V57L (on ENST00000372045; = p.V63L on NM_145234.4) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.996); catalogued as COSV54326173; called by muse, mutect2, varscan2
- CHST8 | c.150G>T p.R50S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV52860010; called by muse, mutect2, varscan2
- CLEC16A | c.1169G>C p.R390T | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV68500356; called by muse, mutect2, varscan2
- CLEC4F | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as rs1403143830, COSV55480049; called by muse, mutect2, varscan2
- CLIP4 | c.2089G>T p.G697W | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60749978; called by muse, mutect2, varscan2
- CLVS2 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV51564675; called by muse, mutect2, varscan2
- CNTN1 | c.2368A>G p.K790E | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV61641460; called by muse, mutect2, varscan2
- CNTN5 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54281128, COSV54323217, COSV54370562; called by muse, mutect2, varscan2
- COL11A1 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV62175793, COSV62187314, COSV62198658; called by muse, mutect2, varscan2
- COL24A1 | c.1466G>C p.G489A | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV65308386; called by muse, mutect2
- COL25A1 | c.83C>G p.A28G | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV67652248; called by muse, mutect2, varscan2
- COL2A1 | c.1726G>A p.G576S | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61531785; called by muse, mutect2, varscan2
- COL4A4 | c.2599G>C p.G867R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV61633490, COSV61635192; called by muse, mutect2, varscan2
- COL5A1 | c.4361C>T p.S1454F | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as rs781445285, COSV65670696; called by muse, mutect2, varscan2
- COL5A2 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs758092388, COSV66411000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CORIN | c.1616G>T p.R539L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56693680; called by muse, mutect2, varscan2
- CORO2A | c.789G>C p.M263I | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV59663597; called by muse, mutect2
- CPXM2 | c.1359C>A p.N453K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV53864630; called by muse, mutect2, varscan2
- CPZ | c.1244C>G p.S415C (on ENST00000360986 / NM_001014447.3; = p.S404C on NM_003652.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV59923818; called by muse, mutect2, varscan2
- CRACD | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51724444, COSV51731812; called by muse, mutect2, varscan2
- CSMD1 | c.8318G>A p.G2773D (on ENST00000520002; = p.G2772D on NM_033225.6) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1486284693, COSV59340413; called by muse, mutect2, varscan2
- CSMD3 | c.4522G>T p.D1508Y (on ENST00000297405 / NM_001363185.1; = p.D1404Y on NM_052900.3) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52219365, COSV99840016; called by mutect2, varscan2
- CTC1 | c.2630C>G p.S877* | Nonsense Mutation (SNP) | VAF 17/69 reads (25%) | catalogued as COSV59853828; called by muse, mutect2, varscan2
- CYP2E1 | c.1439G>T p.C480F | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as COSV53313924; called by muse, mutect2, varscan2
- DAGLA | c.1067G>T p.R356L | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57197007, COSV57197345; called by muse, mutect2, varscan2
- DDX3Y | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.276); catalogued as COSV60177017; called by muse, mutect2
- DDX50 | c.1670G>A p.G557D | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as COSV65292666; called by muse, mutect2, varscan2
- DENND3 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV52803632; called by muse, varscan2
- DLK1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as rs754301250, COSV57992194; called by muse, mutect2, varscan2
- DMD | c.6827C>T p.P2276L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58902290; called by muse, mutect2, varscan2
- DMD | c.1156A>G p.M386V | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55880528; called by muse, mutect2, varscan2
- DNAH10 | c.1876C>T p.H626Y (on ENST00000409039; = p.H565Y on NM_207437.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs201354171, COSV68995947; called by muse, mutect2, varscan2
- DOCK1 | c.2812A>G p.I938V | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs552636749, COSV54745607; called by muse, mutect2, varscan2
- DUSP11 | c.935+1G>A p.X312_splice | Splice Site (SNP) | VAF 19/76 reads (25%) | catalogued as COSV55594983; called by muse, mutect2, varscan2
- EGFLAM | c.823G>C p.E275Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV59303056, COSV59306723; called by muse, mutect2
- EGFR | c.898G>A p.V300M | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51813309; called by muse, mutect2, varscan2
- ELMO1 | c.1898A>T p.Q633L | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV60295912, COSV60309762; called by muse, mutect2, varscan2
- ELOA | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.34); catalogued as COSV69310601; called by muse, mutect2, varscan2
- EYA2 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57945687; called by muse, mutect2, varscan2
- FAM199X | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV55433964; called by muse, mutect2, varscan2
- FAM47B | c.16C>A p.P6T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.32); PolyPhen benign (0.215); catalogued as COSV61454741, COSV61455586; called by muse, mutect2, varscan2
- FAM47C | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs149671724, COSV63725620; called by muse, mutect2, varscan2
- FAT3 | c.3688G>T p.G1230C | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53130405; called by muse, mutect2, varscan2
- FBXO15 | c.1504del p.I502Sfs*20 | Frame Shift Del (DEL) | VAF 24/143 reads (17%) | catalogued as rs1438282903; called by mutect2, pindel, varscan2
- FBXW11 | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV51608468, COSV51610604; called by muse, mutect2, varscan2
- FCMR | c.625A>G p.T209A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1001936972, COSV65568217; called by muse, mutect2, varscan2
- FGF6 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57404328, COSV57404424; called by muse, mutect2, varscan2
- FIP1L1 | c.622A>G p.T208A | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1308448534, COSV60997546; called by muse, mutect2, varscan2
- FOXA2 | c.472G>T p.A158S (on ENST00000377115 / NM_153675.3; = p.A164S on NM_021784.5) | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs745424789, COSV65796267, COSV65796554; called by muse, mutect2, varscan2
- FOXF2 | c.1109G>C p.S370T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV52526477; called by muse, mutect2
- FZD3 | c.692T>G p.F231C | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53536240; called by muse, mutect2, varscan2
- GAD1 | c.699G>C p.M233I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60152952; called by muse, mutect2, varscan2
- GFI1B | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148728985; called by muse, mutect2, varscan2
- GGT6 | c.1363G>A p.E455K (on ENST00000574154 / NM_001122890.3; = p.E423K on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.027); catalogued as COSV54596903; called by muse, mutect2, varscan2
- GLMP | c.632A>G p.H211R | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55295858; called by muse, mutect2, varscan2
- GRAMD1C | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63983094; called by muse, mutect2, varscan2
- GRIK3 | c.470C>A p.A157D | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV66141701; called by muse, mutect2, varscan2
- GRM8 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.142); catalogued as COSV58837738; called by muse, mutect2, varscan2
- GSDMA | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.697); catalogued as COSV56977536; called by muse, mutect2, varscan2
- GTF3C1 | c.2591G>T p.G864V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.033); catalogued as COSV62242275; called by muse, mutect2, varscan2
- H3C7 | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.406); catalogued as COSV55100188; called by muse, mutect2, varscan2
- H4C4 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs764927627, COSV61591312; called by muse, mutect2, varscan2
- HCN4 | c.2492C>A p.S831Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.395); catalogued as COSV56084672; called by muse, mutect2, varscan2
- HDAC9 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67776354; called by muse, mutect2, varscan2
- HECW1 | c.136G>T p.D46Y | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.524); catalogued as COSV67832285, COSV67832713; called by muse, mutect2, varscan2
- HELZ2 | c.6587A>G p.Q2196R (on ENST00000467148 / NM_001037335.2; = p.Q1627R on NM_033405.3) | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV71296216; called by muse, mutect2, varscan2
- HERC2 | c.7826G>T p.C2609F | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV55330445; called by muse, mutect2, varscan2
- HERC2 | c.3904C>G p.L1302V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55311405; called by muse, mutect2, varscan2
- HOXD10 | c.923G>A p.R308K | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50892833; called by muse, mutect2, varscan2
- HS3ST4 | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100502671; called by muse, mutect2, varscan2
- HS3ST5 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV57144055; called by muse, mutect2, varscan2
- HSPA2 | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV55970328; called by muse, mutect2, varscan2
- HTR1E | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100541213, COSV59508784; called by muse, mutect2, varscan2
- HTR3A | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV55470174; called by muse, mutect2, varscan2
- HTT | c.2456C>G p.S819C | Missense Mutation (SNP) | VAF 41/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61864372; called by muse, mutect2, varscan2
- HYDIN | c.15108C>A p.Y5036* | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as COSV66639830; called by muse, mutect2, varscan2
- IGLV2-14 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 64/236 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.635); catalogued as rs776748279; called by muse, mutect2, varscan2
- INHBC | c.431C>G p.T144S | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as COSV100548046; called by muse, mutect2, varscan2
- IQCJ | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101188767, COSV67337569; called by muse, mutect2, varscan2
- KCNN2 | c.301C>G p.H101D (on ENST00000264773; = p.H313D on NM_021614.4) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV53291853; called by muse, mutect2, varscan2
- KCNU1 | c.2258T>C p.F753S | Missense Mutation (SNP) | VAF 26/615 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV67757295; called by muse, mutect2
- KDM5C | c.769C>G p.L257V | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV64765882; called by muse, mutect2, varscan2
- KIF2B | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52132166; called by muse, varscan2
- KIRREL2 | c.522G>T p.Q174H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.694); catalogued as COSV52877483; called by muse, mutect2, varscan2
- KLHL6 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV58067330; called by muse, mutect2, varscan2
- KLK12 | c.373C>G p.Q125E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV51577599; called by muse, mutect2, varscan2
- KRT79 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371406453; called by muse, mutect2, varscan2
- LCA5L | c.838-1G>C p.X280_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV55745707; called by muse, mutect2, varscan2
- LCE1F | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57669441; called by muse, mutect2, varscan2
- LHFPL1 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 91/156 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV63183111; called by muse, mutect2, varscan2
- LNX1 | c.1471A>C p.S491R (on ENST00000263925 / NM_001126328.3; = p.S395R on NM_032622.2) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV55787604; called by muse, varscan2
- LRIT2 | c.605G>T p.W202L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60563662; called by muse, mutect2, varscan2
- LRP1B | c.7964C>G p.P2655R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV101260046; called by muse, mutect2, varscan2
- LRP1B | c.7963C>A p.P2655T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1262109203, COSV101260047; called by muse, mutect2, varscan2
- LRRC37A3 | c.3832G>T p.A1278S | Missense Mutation (SNP) | VAF 57/98 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58535772; called by muse, mutect2, varscan2
- MAGEB1 | c.305G>T p.S102I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.081); catalogued as COSV66775971; called by muse, mutect2, varscan2
- MAGEC2 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 57/96 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV56000083; called by muse, mutect2, varscan2
- MAJIN | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.248); catalogued as rs759529065, COSV54164678; called by muse, mutect2, varscan2
- MC4R | c.851T>A p.F284Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100235967, COSV55352494; called by muse, mutect2, varscan2
- MEFV | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.797); catalogued as COSV54823724, COSV99560128; called by muse, mutect2, varscan2
- MEP1A | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770961433, COSV100043055; called by muse, mutect2, varscan2
- MGAM | c.5057A>T p.Y1686F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV72074949; called by muse, mutect2, varscan2
- MRTFB | c.2667C>G p.I889M (on ENST00000571589 / NM_001365412.2; = p.I839M on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.499); catalogued as COSV57959005; called by muse, mutect2, varscan2
- MTX2 | c.342C>G p.Y114* | Nonsense Mutation (SNP) | VAF 34/158 reads (22%) | catalogued as COSV50888408; called by muse, mutect2, varscan2
- MYBPH | c.985G>T p.D329Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55142953; called by muse, mutect2, varscan2
- MYO1E | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55689712; called by muse, mutect2, varscan2
- NBR1 | c.513G>C p.E171D | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV57833455; called by muse, mutect2, varscan2
- NDNF | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV65633917; called by muse, mutect2, varscan2
- NELFE | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV64812441; called by muse, mutect2
- NEXMIF | c.3634C>G p.P1212A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV50043090; called by muse, mutect2, varscan2
- NEXMIF | c.3410A>T p.Q1137L | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV50043152; called by muse, mutect2, varscan2
- NPNT | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59754820; called by muse, mutect2, varscan2
- NPY1R | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV56715067; called by muse, mutect2, varscan2
- NRAP | c.2252A>C p.Y751S (on ENST00000359988 / NM_001322945.2; = p.Y716S on NM_006175.4) | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63491765; called by muse, mutect2, varscan2
- NRP1 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 34/108 reads (31%) | catalogued as COSV55162901; called by muse, mutect2, varscan2
- NSUN2 | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV52955244; called by muse, mutect2, varscan2
- NUPR1 | c.113-4A>C | Splice Region (SNP) | VAF 35/148 reads (24%) | catalogued as rs780793494, COSV100257181, COSV100257234; called by muse, mutect2, varscan2
- OAS2 | c.1237G>T p.V413L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as rs181098272, COSV60803036; called by muse, mutect2, varscan2
- OFD1 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60796702, COSV60797921; called by muse, mutect2, varscan2
- OR13C2 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV73377735; called by muse, mutect2, varscan2
- OR13C5 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV66164801; called by muse, mutect2, varscan2
- OR14K1 | c.148G>T p.D50Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99315434; called by muse, mutect2, varscan2
- OR2A14 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 60/271 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs778336071, COSV68718311; called by muse, mutect2, varscan2
- OR2T11 | c.338del p.G113Afs*15 | Frame Shift Del (DEL) | VAF 21/113 reads (19%) | catalogued as COSV100424759, COSV100424886; called by mutect2, pindel, varscan2
- OR4K1 | c.683G>T p.R228M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); catalogued as COSV53460769; called by muse, mutect2, varscan2
- OR4N2 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 68/274 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs757493913, COSV60050391, COSV60050868, COSV60052488; called by muse, mutect2, varscan2
- OR6B1 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV68770312; called by muse, mutect2, varscan2
- OR6K2 | c.812G>T p.W271L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as COSV62743688; called by muse, mutect2, varscan2
- ORMDL2 | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV54478727; called by muse, mutect2, varscan2
- OSBPL11 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56173019, COSV56174625; called by muse, mutect2, varscan2
- PALLD | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV54984271; called by muse, mutect2, varscan2
- PAPPA2 | c.5044G>T p.V1682L | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62801266; called by muse, mutect2, varscan2
- PAQR3 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs780215554, COSV55010323; called by muse, mutect2, varscan2
- PARP2 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as rs754797447, COSV51640221, COSV99162979; called by muse, mutect2, varscan2
- PCDHA3 | c.1840G>A p.G614R | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs782532560, COSV63542996; called by muse, mutect2, varscan2
- PCDHA8 | c.1484T>A p.V495E | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV65328104; called by muse, mutect2, varscan2
- PCLO | c.5459G>T p.R1820M | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61643950, COSV61662642; called by muse, mutect2, varscan2
- PCLO | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 114/389 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV61643966; called by muse, mutect2, varscan2
- PDE11A | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.327); catalogued as rs147662486, COSV53698732; called by muse, mutect2
- PFKFB2 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 35/113 reads (31%) | PolyPhen probably damaging (0.996); catalogued as rs371999507; called by muse, mutect2, varscan2
- PFKL | c.267C>G p.C89W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62463980; called by muse, mutect2, varscan2
- PHF8 | c.2330C>G p.S777C (on ENST00000357988 / NM_001184896.1; = p.S741C on NM_015107.3) | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV57683382; called by muse, mutect2, varscan2
- PIK3R4 | c.3572C>G p.S1191* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100768340, COSV63241695; called by muse, mutect2, varscan2
- PLA1A | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV56332404; called by muse, mutect2, varscan2
- PLPPR4 | c.1018C>A p.H340N | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.157); catalogued as COSV64566555; called by muse, mutect2, varscan2
- PLXNA4 | c.657T>A p.H219Q | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV58136705; called by muse, mutect2, varscan2
- POLQ | c.1802G>T p.S601I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs758650458, COSV51754720; called by muse, mutect2, varscan2
- PPP1R16B | c.739C>T p.L247F | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as rs887277295, COSV55379457; called by muse, mutect2, varscan2
- PPRC1 | c.2206G>C p.E736Q | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1429748197, COSV53386454; called by muse, mutect2, varscan2
- PREX1 | c.2348G>A p.G783D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.564); catalogued as COSV64253411; called by muse, mutect2, varscan2
- PRKD1 | c.1457G>T p.G486V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV100121395, COSV59569283; called by muse, mutect2, varscan2
- PRKD1 | c.1456G>T p.G486W | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100121400; called by muse, mutect2, varscan2
- PROS1 | c.165A>C p.E55D | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62398847; called by muse, mutect2, varscan2
- PRR16 | c.253A>G p.S85G (on ENST00000407149 / NM_001300783.2; = p.S62G on NM_016644.2) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65397601, COSV65398704; called by muse, mutect2, varscan2
- PSG8 | c.1120C>A p.L374I | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.73); catalogued as COSV60612950; called by muse, mutect2, varscan2
- PTPN5 | c.197C>A p.S66* | Nonsense Mutation (SNP) | VAF 62/151 reads (41%) | catalogued as COSV62126788; called by muse, mutect2, varscan2
- PTPRC | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV61414421; called by muse, mutect2, varscan2
- RAD51B | c.957G>A p.Q319= | Splice Region (SNP) | VAF 7/39 reads (18%) | catalogued as CS159241, COSV66849960; called by muse, mutect2, varscan2
- RASAL1 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.072); catalogued as COSV55657262; called by muse, mutect2, varscan2
- RBM5 | c.398A>T p.K133M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100762468; called by muse, mutect2
- RBM5 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV100762469; called by muse, mutect2
- RBPJ | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.176); catalogued as COSV60752996; called by muse, mutect2
- RGS7 | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV58546654; called by muse, mutect2, varscan2
- RNF10 | c.2137G>T p.A713S | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV58046227; called by muse, mutect2, varscan2
- ROBO3 | c.1726T>A p.W576R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as HM070122, COSV67301185; called by muse, mutect2
- ROR1 | c.1158T>A p.C386* | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV64288959; called by muse, mutect2, varscan2
- RPUSD4 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.015); catalogued as COSV53599516; called by muse, mutect2, varscan2
- RSPRY1 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV68027893; called by muse, mutect2, varscan2
- RTN3 | c.223G>C p.D75H (on ENST00000377819 / NM_001265589.2; = p.D56H on NM_201428.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV58029742, COSV58030095; called by muse, mutect2, varscan2
- RUBCN | c.2171G>T p.C724F | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56368236; called by muse, mutect2, varscan2
- RYR3 | c.7649A>G p.H2550R (on ENST00000389232; = p.H2551R on NM_001036.6) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1282743371, COSV66796135; called by muse, mutect2, varscan2
- S100A7 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100906729, COSV64193475, COSV64193557; called by muse, mutect2, varscan2
- SCAPER | c.1612A>T p.R538* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as COSV57743279; called by muse, mutect2, varscan2
- SCN7A | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV69268892, COSV69272652; called by muse, mutect2, varscan2
- SELENOP | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV100736892; called by muse, mutect2, varscan2
- SENP2 | c.1754A>T p.H585L | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV56195238; called by muse, mutect2, varscan2
- SHC3 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV65438415, COSV65439153; called by muse, mutect2, varscan2
- SIPA1L1 | c.953C>T p.S318L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.452); catalogued as COSV62171140; called by muse, mutect2, varscan2
- SLC12A3 | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402444800, CM121315, CM981829, COSV52636332; called by muse, mutect2, varscan2
- SLC17A6 | c.1099G>T p.G367* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | catalogued as COSV54137810, COSV54141058; called by muse, mutect2, varscan2
- SLC26A4 | c.222G>A p.W74* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as rs1388888912, COSV55917627; called by muse, mutect2, varscan2
- SLC3A1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53223356; called by muse, mutect2, varscan2
- SLC44A5 | c.1190C>T p.T397I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs776537215, COSV63767809; called by muse, mutect2, varscan2
- SLC4A1 | c.2237C>G p.T746S | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV52261130; called by muse, mutect2, varscan2
- SLC9A5 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as rs754815769, COSV55362929; called by muse, mutect2, varscan2
- SLIT3 | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60616113; called by muse, mutect2, varscan2
- SLITRK4 | c.2018A>G p.H673R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV62024719; called by muse, mutect2, varscan2
- SMG1 | c.2399A>T p.D800V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV67172579; called by muse, varscan2
- SMG6 | c.2166G>T p.L722F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53969791; called by muse, mutect2, varscan2
- SMYD1 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV70225418; called by muse, mutect2, varscan2
- SNX4 | c.928dup p.Y310Lfs*13 | Frame Shift Ins (INS) | VAF 7/37 reads (19%) | catalogued as rs755489010; called by mutect2, pindel, varscan2
- SORBS1 | c.2735C>A p.T912K (on ENST00000361941 / NM_001034954.2; = p.T562K on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV53359791; called by muse, mutect2, varscan2
- SORBS2 | c.221G>T p.G74V (on ENST00000284776 / NM_021069.5; = p.G120V on NM_003603.6) | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53004559; called by muse, mutect2, varscan2
- SPART | c.1286C>T p.S429L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100768773, COSV62086378; called by muse, mutect2, varscan2
- SPATA31A3 | c.2753A>T p.Q918L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs1456742502; called by mutect2, varscan2
- SPDYE5 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV71596362; called by muse, mutect2, varscan2
- SPTA1 | c.5190-2A>T p.X1730_splice | Splice Site (SNP) | VAF 29/109 reads (27%) | catalogued as CS961697, COSV63753876; called by muse, mutect2, varscan2
- SRGAP3 | c.3049G>T p.V1017F | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as COSV64535231; called by muse, mutect2, varscan2
- STAC | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1177489353, COSV56213302; called by muse, mutect2, varscan2
- SYNE1 | c.9023C>T p.A3008V (on ENST00000367255 / NM_182961.4; = p.A3015V on NM_033071.3) | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as rs1261645409, COSV55017771; called by muse, mutect2, varscan2
- SYNE2 | c.4337T>A p.V1446E | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV59955765; called by muse, mutect2, varscan2
- SYNE2 | c.10636G>C p.G3546R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs772491043, COSV59955772; called by mutect2, varscan2
- SYTL4 | c.1947C>A p.Y649* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | catalogued as COSV52168759; called by muse, mutect2, varscan2
- TBC1D24 | c.1542G>C p.Q514H (on ENST00000646147 / NM_001199107.2; = p.Q508H on NM_020705.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.071); catalogued as COSV53547104; called by muse, mutect2, varscan2
- TBX15 | c.1252G>C p.D418H (on ENST00000369429 / NM_001330677.2; = p.D312H on NM_152380.3) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); catalogued as COSV52872729; called by muse, mutect2, varscan2
- TDRD5 | c.1926C>G p.N642K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.573); catalogued as COSV54245008, COSV99676002; called by muse, mutect2, varscan2
- TENM3 | c.4994C>G p.S1665* | Nonsense Mutation (SNP) | VAF 44/90 reads (49%) | catalogued as COSV69311662, COSV69312693; called by muse, mutect2, varscan2
- TET2 | c.724G>T p.V242L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV54417709; called by muse, mutect2, varscan2
- TEX15 | c.3812T>A p.L1271* (on ENST00000256246; = p.L1654* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 20/46 reads (43%) | catalogued as COSV56348327; called by muse, mutect2, varscan2
- TLCD3B | c.351C>A p.S117R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV54227485; called by muse, mutect2, varscan2
- TLN2 | c.3734A>T p.N1245I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60891295; called by muse, mutect2, varscan2
- TLR4 | c.2181C>A p.F727L (on ENST00000355622 / NM_138554.5; = p.F687L on NM_003266.4) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV62922746, COSV62923624; called by muse, mutect2, varscan2
- TMEM220 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.436); catalogued as COSV59379602; called by muse, mutect2, varscan2
- TMEM30B | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV63133771; called by muse, mutect2, varscan2
- TMPRSS13 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV70626604; called by muse, mutect2, varscan2
- TNIP3 | c.878A>C p.E293A | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV50249582; called by muse, mutect2
- TNS1 | c.2102C>T p.S701F | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs913987467, COSV50690228, COSV50715637; called by muse, mutect2, varscan2
- TPI1 | c.196C>G p.L66V (on ENST00000229270; = p.L29V on NM_000365.6) | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV57538319; called by muse, mutect2, varscan2
- TPO | c.1828A>T p.S610C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.708); catalogued as COSV61104377; called by muse, mutect2, varscan2
- TRANK1 | c.7444C>G p.L2482V | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV57154273; called by muse, mutect2, varscan2
- TRAPPC9 | c.1764A>T p.K588N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66902528; called by muse, mutect2, varscan2
- TRIB3 | c.184G>C p.V62L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as COSV53931754; called by muse, mutect2, varscan2
- TRPA1 | c.2044C>A p.P682T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV51565228; called by muse, mutect2, varscan2
- TRPC5 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53294167; called by muse, mutect2, varscan2
- TSPAN11 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV53819275; called by muse, mutect2, varscan2
- TTN | c.4234A>G p.R1412G (on ENST00000591111; = p.R1366G on NM_003319.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | PolyPhen possibly damaging (0.889); catalogued as COSV60150135; called by muse, mutect2, varscan2
- TUBD1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57873305; called by muse, mutect2, varscan2
- UBC | c.413A>G p.Q138R | Missense Mutation (SNP) | VAF 52/213 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.483); catalogued as rs982018752, COSV60060009; called by muse, mutect2, varscan2
- UBR1 | c.3155A>T p.Y1052F | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.193); catalogued as COSV51931904; called by muse, mutect2, varscan2
- UCHL1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 26/120 reads (22%) | catalogued as COSV52652053; called by muse, mutect2, varscan2
- UHRF1BP1 | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51957021; called by muse, mutect2, varscan2
- ULK1 | c.2137G>T p.D713Y | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); catalogued as COSV58857779; called by muse, mutect2, varscan2
- UNC45B | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52097247; called by muse, mutect2, varscan2
- UNC5A | c.1789C>G p.L597V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.07); catalogued as COSV52841590; called by muse, mutect2, varscan2
- UNC79 | c.1866G>C p.E622D (on ENST00000393151 / NM_001346218.2; = p.E445D on NM_020818.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV56384583; called by muse, mutect2, varscan2
- USP7 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61215540; called by muse, mutect2, varscan2
- VN1R4 | c.538C>A p.R180S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs764126508, COSV60804821; called by muse, mutect2
- VSIG1 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV54260091; called by muse, mutect2, varscan2
- WDR17 | c.1619G>T p.G540V | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54576733; called by muse, mutect2, varscan2
- WDR36 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV72411273; called by muse, mutect2, varscan2
- WDR49 | c.1043C>G p.S348C (on ENST00000308378 / NM_001366158.1; = p.S689C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57710825; called by muse, mutect2, varscan2
- WDR59 | c.484A>C p.N162H | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV50937274; called by muse, mutect2, varscan2
- WDR70 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV54275722; called by muse, mutect2, varscan2
- WNT9A | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs749997833, COSV55294622; called by muse, mutect2, varscan2
- XIRP2 | c.1184T>G p.L395R (on ENST00000628543; = p.L570R on NM_152381.6) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54710620; called by muse, mutect2, varscan2
- ZFHX4 | c.4102G>T p.V1368L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51450085; called by muse, mutect2, varscan2
- ZNF131 | c.1825G>C p.E609Q (on ENST00000509156 / NM_001330707.2; = p.E575Q on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.025); catalogued as COSV61003089; called by muse, mutect2, varscan2
- ZNF682 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs372296532; called by muse, mutect2, varscan2
- ZNF800 | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.191); catalogued as COSV56177574; called by muse, mutect2, varscan2
- ZNF827 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV65228677; called by muse, mutect2, varscan2
- ZNF92 | c.922A>G p.M308V (on ENST00000328747 / NM_152626.4; = p.M239V on NM_007139.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs767525066, COSV60874664; called by muse, mutect2, varscan2
- ACOX3 | c.171del p.N57Kfs*21 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- ADAD1 | c.141del p.K48Rfs*9 | Frame Shift Del (DEL) | VAF 21/88 reads (24%) | called by mutect2, pindel, varscan2
- ANKRD20A1 | c.1948A>C p.I650L | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATG9B | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- CCDC57 | c.529del p.E177Sfs*20 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- DENND2A | c.589del p.A197Qfs*120 | Frame Shift Del (DEL) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- EIF2A | c.1315_1316insCAG p.E438_E439insA | In Frame Ins (INS) | VAF 24/110 reads (22%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.28del p.V11Lfs*4 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | called by mutect2, pindel, varscan2
- IGKV2D-30 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NCOA4 | c.802A>C p.S268R | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- NUP58 | c.235_236insCG p.G79Afs*8 | Frame Shift Ins (INS) | VAF 8/64 reads (13%) | called by mutect2, varscan2
- OR8U1 | c.596T>A p.I199N | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PHKA2 | c.3068dup p.Q1025Pfs*38 | Frame Shift Ins (INS) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- POLR1B | c.392del p.K131Sfs*11 | Frame Shift Del (DEL) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- PSTK | c.1044del p.*349Efs*10 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.144del p.K49Rfs*80 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- SERPINA3 | c.246del p.A83Pfs*14 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel, varscan2
- TULP1 | c.1504dup p.I502Nfs*147 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | called by mutect2, pindel, varscan2
- ADAMTS7 | c.4293G>T p.A1431= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV66307951; called by muse, mutect2, varscan2
- AHNAK2 | c.10755G>C p.L3585= | Silent (SNP) | VAF 45/236 reads (19%) | catalogued as rs370843314, COSV60911766, COSV60919204; called by muse, mutect2, varscan2
- ANO6 | c.1905A>G p.R635= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV57663067; called by muse, mutect2, varscan2
- ARFGEF1 | c.3975G>A p.K1325= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs1323027707, COSV51611154; called by muse, mutect2, varscan2
- ARHGEF37 | c.391C>T p.L131= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV61369156; called by muse, mutect2, varscan2
- ATP10B | c.3777C>T p.L1259= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs369390293; called by muse, mutect2, varscan2
- ATP2A3 | c.1500C>T p.P500= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs780528289, COSV59230826; called by muse, mutect2, varscan2
- BCL2 | c.333C>T p.D111= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV61383758; called by muse, mutect2, varscan2
- BRSK2 | c.1158C>T p.L386= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV57541839, COSV57544638; called by muse, mutect2, varscan2
- CACNA1F | c.4504C>A p.R1502= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV59905169; called by muse, mutect2, varscan2
- CEBPE | c.51A>T p.P17= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52830103; called by muse, mutect2, varscan2
- CES5A | c.480C>A p.S160= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV51865364, COSV51867668; called by muse, mutect2, varscan2
- CHRM5 | c.681G>T p.L227= | Silent (SNP) | VAF 73/211 reads (35%) | catalogued as COSV67247744; called by muse, mutect2, varscan2
- COLEC12 | c.918C>T p.A306= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV68371545; called by muse, mutect2, varscan2
- CX3CR1 | c.78C>A p.I26= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV64193670, COSV64194275; called by muse, mutect2, varscan2
- DDX24 | c.501G>A p.Q167= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV58212879; called by muse, mutect2, varscan2
- DUOX2 | c.1107C>T p.V369= | Silent (SNP) | VAF 30/124 reads (24%) | catalogued as COSV59908817; called by muse, mutect2, varscan2
- EI24 | c.408G>T p.V136= | Silent (SNP) | VAF 31/142 reads (22%) | catalogued as COSV54019943; called by muse, mutect2, varscan2
- F13A1 | c.507C>G p.G169= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV53559219, COSV53561024; called by muse, mutect2, varscan2
- FCRL3 | c.1791C>A p.A597= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV63842734; called by muse, mutect2, varscan2
- GRIN3A | c.2316G>A p.K772= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV62452816; called by muse, mutect2, varscan2
- GSDMA | c.118C>T p.L40= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV56977514; called by muse, mutect2, varscan2
- HCN4 | c.1278C>T p.L426= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV56084681; called by muse, mutect2, varscan2
- HIPK4 | c.1188T>A p.A396= | Silent (SNP) | VAF 21/79 reads (27%) | catalogued as COSV52522058; called by muse, mutect2, varscan2
- HJV | c.153G>C p.L51= | Silent (SNP) | VAF 23/104 reads (22%) | catalogued as COSV60952382; called by muse, mutect2, varscan2
- HS3ST4 | c.1050C>A p.S350= | Silent (SNP) | VAF 26/144 reads (18%) | catalogued as COSV100502669, COSV58804913; called by muse, mutect2, varscan2
- IGLL1 | c.352C>T p.L118= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV50770059; called by muse, mutect2, varscan2
- INHBC | c.432C>A p.T144= | Silent (SNP) | VAF 51/190 reads (27%) | catalogued as COSV100548048; called by muse, mutect2, varscan2
- IRS1 | c.2061C>T p.N687= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs757010026, COSV59337484; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGB8 | c.1980A>G p.S660= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV56010362; called by muse, mutect2, varscan2
- KIF2B | c.204C>A p.G68= | Silent (SNP) | VAF 58/131 reads (44%) | catalogued as COSV52132157; called by muse, varscan2
- KIT | c.270C>T p.T90= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV55407084; called by muse, mutect2, varscan2
- LRP1B | c.5214A>T p.L1738= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV67238032; called by muse, mutect2, varscan2
- MAP2 | c.4875C>A p.T1625= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as COSV52290862, COSV52296139; called by muse, mutect2, varscan2
- MKI67 | c.9306A>G p.E3102= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV64075186; called by muse, mutect2, varscan2
- MOG | c.375C>T p.F125= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV65321362; called by muse, mutect2, varscan2
- MRC1 | c.2134C>T p.L712= | Silent (SNP) | VAF 110/437 reads (25%) | called by muse, mutect2, varscan2
- MRPL39 | c.39C>G p.L13= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV56261200; called by muse, mutect2, varscan2
- MYO5B | c.750C>T p.V250= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV53217910, COSV53222195, COSV53224785; called by muse, mutect2, varscan2
- NAALAD2 | c.1102C>A p.R368= | Silent (SNP) | VAF 32/128 reads (25%) | catalogued as COSV58962344; called by muse, mutect2, varscan2
- NCAPG2 | c.435G>A p.Q145= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV51988936; called by muse, mutect2, varscan2
- NLRP14 | c.3135A>T p.L1045= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV55068494; called by muse, mutect2, varscan2
- NLRP7 | c.724C>T p.L242= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as COSV60176589; called by muse, mutect2, varscan2
- NXPE4 | c.606G>A p.V202= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV64943963; called by muse, mutect2
- OR12D2 | c.759T>A p.P253= | Silent (SNP) | VAF 43/166 reads (26%) | catalogued as COSV65828450; called by muse, mutect2, varscan2
- OR52E4 | c.588C>A p.I196= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV57624215; called by muse, mutect2, varscan2
- OR9Q2 | c.63C>G p.L21= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV61112171; called by muse, mutect2, varscan2
- PCDHA5 | c.1980C>T p.A660= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV65353667; called by muse, mutect2, varscan2
- PCDHGB4 | c.1860C>A p.R620= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as COSV53972270; called by muse, mutect2, varscan2
- PDGFRA | c.3207C>T p.D1069= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as COSV57269890; called by muse, mutect2, varscan2
- PDZD4 | c.231C>T p.T77= | Silent (SNP) | VAF 20/27 reads (74%) | catalogued as COSV51247784; called by muse, mutect2, varscan2
- PLEC | c.2505G>T p.A835= (on ENST00000322810 / NM_201380.4; = p.A725= on NM_000445.5) | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs373347166, COSV59652265; called by muse, mutect2, varscan2
- POLG | c.2004G>C p.L668= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV51522618; called by muse, mutect2, varscan2
- POLI | c.1287C>A p.T429= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV54189348, COSV54190169; called by muse, mutect2, varscan2
- PPP1R3A | c.2211A>T p.S737= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV52885384; called by muse, mutect2, varscan2
- PSG7 | c.1233C>A p.V411= | Silent (SNP) | VAF 89/209 reads (43%) | catalogued as COSV68445480; called by muse, mutect2, varscan2
- RIMBP2 | c.1854C>T p.H618= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs774732133, COSV55476240; called by muse, mutect2, varscan2
- RING1 | c.969C>T p.A323= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs769737800, COSV63002672; called by muse, mutect2, varscan2
- ROBO3 | c.1803A>T p.T601= | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as COSV67301191; called by muse, mutect2, varscan2
- SH3BP4 | c.2364G>C p.R788= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs761053542, COSV60644478; called by muse, mutect2, varscan2
- SLC16A10 | c.687C>T p.G229= | Silent (SNP) | VAF 27/89 reads (30%) | catalogued as COSV64354547; called by muse, mutect2, varscan2
- SLC35A1 | c.57G>A p.V19= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV65780287; called by muse, mutect2, varscan2
- SLC35A2 | c.750C>G p.L250= | Silent (SNP) | VAF 3/9 reads (33%) | catalogued as rs375311728, COSV54430869; ClinVar: likely benign; called by muse, mutect2
- SMYD5 | c.63C>T p.V21= | Silent (SNP) | VAF 47/196 reads (24%) | catalogued as rs746354027, COSV50265174; called by muse, mutect2
- SYNE1 | c.23316G>C p.R7772= (on ENST00000367255 / NM_182961.4; = p.R7701= on NM_033071.3) | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV55017732; called by muse, mutect2, varscan2
- TECPR2 | c.2589C>T p.L863= | Silent (SNP) | VAF 19/117 reads (16%) | catalogued as rs1382296444, COSV63971554, COSV63971654; called by muse, mutect2, varscan2
- TKTL2 | c.987G>C p.L329= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as COSV54919693; called by muse, mutect2, varscan2
- TMEM108 | c.648C>A p.I216= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV58874487, COSV58878810; called by muse, mutect2, varscan2
- TNR | c.1617C>T p.G539= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1243118955, COSV54894102; called by muse, mutect2, varscan2
- TRGV4 | c.144C>A p.T48= | Silent (SNP) | VAF 20/86 reads (23%) | called by muse, mutect2
- TRPS1 | c.2571A>C p.P857= (on ENST00000220888 / NM_001330599.2; = p.P870= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV55247794; called by muse, mutect2, varscan2
- UBE2D1 | c.180T>C p.Y60= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV64218511; called by muse, mutect2, varscan2
- UGT2B10 | c.1428A>T p.R476= | Silent (SNP) | VAF 50/273 reads (18%) | catalogued as COSV55321591; called by muse, mutect2, varscan2
- UNC45A | c.243A>T p.A81= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV57746222; called by muse, mutect2, varscan2
- WDR19 | c.2485C>A p.R829= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as rs775181779, COSV56466070, COSV56467679; called by muse, mutect2, varscan2
- XIRP2 | c.15G>A p.Q5= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54709288; called by muse, mutect2, varscan2
- XIRP2 | c.4740G>A p.L1580= (on ENST00000628543; = p.L1755= on NM_152381.6) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs776633208, COSV54710630; called by muse, mutect2, varscan2
- ZNF423 | c.717C>T p.F239= (on ENST00000563137 / NM_001379286.1; = p.F231= on NM_015069.4) | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV52194323; called by muse, varscan2
- ZNF423 | c.651C>G p.L217= (on ENST00000563137 / NM_001379286.1; = p.L209= on NM_015069.4) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs761474474, COSV52190452; called by muse, varscan2
- ZNF676 | c.1401C>T p.S467= (on ENST00000650058; = p.S435= on NM_001001411.3) | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV68093540; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81157037 G>T | 3'Flank (SNP) | VAF 3/19 reads (16%) | catalogued as rs1339756425; called by muse, mutect2
- AL353804.7 | chrX:73846490 G>A | 5'Flank (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7784del | Intron (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- HLA-L | n.874T>C | RNA (SNP) | VAF 46/156 reads (29%) | called by muse, mutect2, varscan2
- MARCHF1 | c.163-40C>G | Intron (SNP) | VAF 9/24 reads (38%) | catalogued as COSV99922203, COSV99922419; called by muse, mutect2, varscan2
- MYH7 | c.*2T>A | 3'UTR (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100806532; called by muse, mutect2, varscan2
- NFASC | c.2471-1349G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100365447; called by muse, mutect2, varscan2
- SH2B2 | chr7:102281887 C>T | 5'Flank (SNP) | VAF 9/55 reads (16%) | catalogued as COSV52935422; called by muse, mutect2, varscan2
- SUSD4 | c.725-5619C>T | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as rs878898338, COSV100663891; called by muse, mutect2, varscan2
- TOR1AIP2 | c.-147+12097G>A | Intron (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100857518; called by muse, mutect2, varscan2
- TRIM8 | c.*441C>G | 3'UTR (SNP) | VAF 18/76 reads (24%) | catalogued as COSV56661011; called by muse, mutect2, varscan2
